Somatic mutation profile of tumor specimen MMRF_1577_3_BM_CD138pos (aliquot MMRF_1577_3_BM_CD138pos_T1_KHS5U_L16538) from MMRF case MMRF_1577, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 42.0 years (15,349 days).
Specimen MMRF_1577_3_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b00a7a05-5bc5-45dd-9bff-85a012a80e21.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1577_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1577_1_PB_Whole_C2_KBS5U_L03504; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bed196c5-6946-4ec7-85b3-7018a9618fe4

The open-access MAF lists 43 somatic variants for this specimen: 15 protein-altering or splice-affecting, 3 silent, 25 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 13, Missense Mutation 13, Intron 9, Silent 3, RNA 2, 5'Flank 1, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGEF40 | c.3647G>A p.R1216Q | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.009); catalogued as rs762930972; called by muse, mutect2, varscan2
- CACNA1B | c.4840G>A p.A1614T | Missense Mutation (SNP) | VAF 33/177 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs747965799, COSV53124044, COSV99500278; called by muse, mutect2, varscan2
- IGHV2-70 | c.293A>G p.Q98R | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.781); catalogued as rs373048671; called by muse, varscan2
- IGHV2-70 | c.289A>G p.N97D | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.213); catalogued as rs368209907; called by muse, varscan2
- IGLV3-1 | c.85G>A p.V29M | Missense Mutation (SNP) | VAF 34/149 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.488); catalogued as rs555443658; called by muse, mutect2, varscan2
- PPP1R15B | c.70T>C p.F24L | Missense Mutation (SNP) | VAF 4/79 reads (5%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.007); catalogued as COSV65815291, COSV65815336; called by muse, mutect2
- TDRD12 | c.2413G>A p.V805I | Missense Mutation (SNP) | VAF 53/156 reads (34%) | SIFT tolerated (0.53); PolyPhen benign (0.005); catalogued as rs986839971; called by muse, mutect2, varscan2
- UNC45B | c.772C>T p.R258W | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.796); catalogued as rs775682897, COSV52093966, COSV99268830; called by muse, mutect2, varscan2
- ABCA12 | c.2472G>T p.K824N (on ENST00000272895 / NM_173076.3; = p.K506N on NM_015657.3) | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DEK | c.-9G>C | Splice Region (SNP) | VAF 29/139 reads (21%) | called by muse, mutect2, varscan2
- MUC16 | c.26465G>T p.R8822I | Missense Mutation (SNP) | VAF 22/176 reads (13%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- PKHD1L1 | c.272A>T p.D91V | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SPG11 | c.4161+2T>A p.X1387_splice | Splice Site (SNP) | VAF 27/142 reads (19%) | called by muse, mutect2, varscan2
- TAS2R20 | c.652G>A p.D218N | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- TRIOBP | c.3487C>T p.P1163S | Missense Mutation (SNP) | VAF 33/197 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.632); called by muse, mutect2, varscan2
- ARHGAP26 | c.222T>C p.D74= | Silent (SNP) | VAF 57/168 reads (34%) | called by muse, mutect2, varscan2
- ATG2A | c.2313A>G p.E771= | Silent (SNP) | VAF 22/154 reads (14%) | called by muse, mutect2, varscan2
- ZFAND3 | c.396A>G p.K132= | Silent (SNP) | VAF 24/121 reads (20%) | called by muse, mutect2, varscan2
- ABCC9 | c.*1605G>C | 3'UTR (SNP) | VAF 16/106 reads (15%) | called by muse, mutect2, varscan2
- ACTG2 | c.366+60A>G | Intron (SNP) | VAF 20/92 reads (22%) | called by muse, mutect2, varscan2
- ADAMTS5 | c.*951G>A | 3'UTR (SNP) | VAF 24/75 reads (32%) | catalogued as rs191038659; called by muse, mutect2, varscan2
- BCKDHB | c.*1079A>G | 3'UTR (SNP) | VAF 16/111 reads (14%) | called by muse, mutect2, varscan2
- C1orf21 | c.*8764C>T | 3'UTR (SNP) | VAF 5/33 reads (15%) | called by muse, mutect2, varscan2
- CCND2 | c.*4457C>A | 3'UTR (SNP) | VAF 23/118 reads (19%) | called by muse, mutect2, varscan2
- CTTN | c.680-180T>G | Intron (SNP) | VAF 19/189 reads (10%) | called by muse, mutect2, varscan2
- CYP8B1 | chr3:42875892 A>G | 5'Flank (SNP) | VAF 22/160 reads (14%) | catalogued as rs905649105; called by muse, mutect2, varscan2
- IER3 | c.*144C>A | 3'UTR (SNP) | VAF 10/57 reads (18%) | called by muse, mutect2, varscan2
- LHX2 | c.*237G>C | 3'UTR (SNP) | VAF 35/108 reads (32%) | called by muse, mutect2, varscan2
- LSS | c.1989-710C>G | Intron (SNP) | VAF 18/102 reads (18%) | catalogued as rs1351070458; called by muse, mutect2, varscan2
- LTB | c.208+89A>C | Intron (SNP) | VAF 19/75 reads (25%) | called by muse, mutect2, varscan2
- NKIRAS1 | c.*295A>G | 3'UTR (SNP) | VAF 12/96 reads (13%) | called by muse, mutect2, varscan2
- OASL | c.1047+141G>A | Intron (SNP) | VAF 13/74 reads (18%) | called by muse, mutect2, varscan2
- OR4K11P | n.567G>A | RNA (SNP) | VAF 22/166 reads (13%) | called by muse, mutect2, varscan2
- PLEKHG4B | c.*6859T>A | 3'UTR (SNP) | VAF 42/230 reads (18%) | called by muse, mutect2, varscan2
- PTDSS2 | c.435+64G>A | Intron (SNP) | VAF 23/60 reads (38%) | called by muse, mutect2, varscan2
- ROBO4 | c.1548-336A>G | Intron (SNP) | VAF 88/332 reads (27%) | called by muse, mutect2, varscan2
- SH3GL2 | c.*349C>T | 3'UTR (SNP) | VAF 14/77 reads (18%) | called by muse, mutect2, varscan2
- SOX11 | c.*5610G>C | 3'UTR (SNP) | VAF 9/44 reads (20%) | called by muse, mutect2, varscan2
- TMEM245 | c.*890A>C | 3'UTR (SNP) | VAF 8/59 reads (14%) | called by muse, mutect2, varscan2
- TTPA | c.*1128A>T | 3'UTR (SNP) | VAF 9/57 reads (16%) | called by muse, mutect2, varscan2
- UBE2DNL | n.627G>A | RNA (SNP) | VAF 41/123 reads (33%) | catalogued as rs1451079701; called by muse, mutect2, varscan2
- UNC13C | c.5457+521_5457+523del | Intron (DEL) | VAF 26/155 reads (17%) | catalogued as rs1454819482; called by pindel, varscan2
- VPS33B | c.1774+33G>A | Intron (SNP) | VAF 9/26 reads (35%) | called by muse, mutect2, varscan2
